Somatic mutation profile of tumor specimen TCGA-XF-AAMF-01A (aliquot TCGA-XF-AAMF-01A-21D-A42E-08) from TCGA case TCGA-XF-AAMF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.5 years (25,023 days).
Specimen TCGA-XF-AAMF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08326f93-a8b1-4120-bf8d-a1cbc38205d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMF-10A (Blood Derived Normal), aliquot TCGA-XF-AAMF-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e21d943-12f8-435d-a958-a2b08321f6f6

The open-access MAF lists 85 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 60, Silent 18, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 5/109 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CD1212290, CM004524, COSV64293413; called by muse, mutect2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2
- ACER1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs370464181; called by muse, varscan2
- ADAM18 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs1246693710, COSV55845508; called by muse, mutect2, varscan2
- AFF1 | c.981G>C p.L327F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV57118400; called by muse, mutect2, varscan2
- ALDH3A1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs774324168, COSV56734860; called by muse, mutect2, varscan2
- APC | c.4717G>C p.E1573Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as CM053766, COSV104439189, COSV57323709, COSV57324336, COSV57334217; called by muse, mutect2, varscan2
- ASPH | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV65243869, COSV65244144; called by muse, mutect2, varscan2
- ATF6 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as COSV63407583; called by muse, mutect2, varscan2
- C4orf19 | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV52649057, COSV52650461; called by muse, mutect2, varscan2
- CD2 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65644030; called by muse, mutect2, varscan2
- CHRNA3 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58774556, COSV58776289; called by muse, mutect2, varscan2
- CNTRL | c.1184G>C p.R395T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53044967, COSV53045263; called by muse, mutect2, varscan2
- COLEC12 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV68369601; called by muse, mutect2
- COMP | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV55874190; called by muse, mutect2, varscan2
- ECI2 | c.761T>C p.L254P (on ENST00000380118 / NM_206836.3; = p.L224P on NM_006117.2) | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60985744; called by muse, mutect2, varscan2
- EEF1A1 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100303480; called by muse, mutect2, varscan2
- EPN2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59060580; called by muse, mutect2, varscan2
- ERBB3 | c.3695G>T p.S1232I | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV57249436; called by muse, mutect2, varscan2
- FBN3 | c.7583-1G>C p.X2528_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV54456894; called by muse, varscan2
- FCGR3A | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV63459256; called by muse, mutect2, varscan2
- FOXA1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1165110401, COSV51644878; called by muse, mutect2, varscan2
- FOXE1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64300272; called by muse, mutect2, varscan2
- GATA3 | c.1310_1311dup p.M438Afs*38 | Frame Shift Ins (INS) | VAF 25/63 reads (40%) | catalogued as COSV60518670; called by mutect2, pindel, varscan2
- GON4L | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs752519380, COSV55190578; called by muse, mutect2, varscan2
- GRIK5 | c.99G>C p.Q33H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV53476663; called by muse, mutect2, varscan2
- GTF3C1 | c.3293C>T p.T1098I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs748587405, COSV100649808; called by muse, varscan2
- HECTD1 | c.1064T>C p.L355S | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.036); catalogued as COSV67945669; called by muse, mutect2, varscan2
- INTS8 | c.1769A>C p.K590T | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV58249545; called by muse, mutect2, varscan2
- ITGB8 | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs755896757, COSV56006456; called by muse, mutect2, varscan2
- KCTD8 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63587221; called by muse, mutect2, varscan2
- KRBA2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV58778874; called by muse, mutect2, varscan2
- KRBA2 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as COSV58778892; called by muse, mutect2, varscan2
- KRT10 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV54089086; called by muse, mutect2, varscan2
- LRP5 | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53713464; called by muse, mutect2, varscan2
- MAEL | c.1236C>G p.N412K | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV63304614, COSV63306055; called by muse, mutect2, varscan2
- MAP1S | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV60722101, COSV60723582; called by muse, mutect2, varscan2
- MCOLN3 | c.1160G>C p.G387A | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV62013537; called by muse, mutect2, varscan2
- MEIS3 | c.956G>T p.R319L (on ENST00000558555 / NM_001346148.1; = p.R365L on NM_020160.3) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100520597, COSV58983763; called by muse, mutect2
- METTL14 | c.1155G>C p.L385F | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV66310399; called by muse, mutect2, varscan2
- MPLKIP | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.522); catalogued as COSV59322496; called by muse, varscan2
- MPLKIP | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV59322502, COSV59337580, COSV59338249; called by muse, varscan2
- MROH6 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV52783634; called by muse, mutect2, varscan2
- MYSM1 | c.1319G>A p.C440Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1156376366, COSV68977237; called by muse, mutect2, varscan2
- NLRP12 | c.771G>C p.Q257H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs1177620093, COSV60745427; called by muse, mutect2, varscan2
- OR2A4 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV59575836; called by muse, mutect2, varscan2
- OR4K5 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV60002841, COSV60002921; called by muse, mutect2, varscan2
- PDE4B | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289148672, COSV58472055; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs377599210; called by muse, mutect2, varscan2
- POSTN | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1177659142, COSV65711766; called by muse, mutect2, varscan2
- RAD21 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.101); catalogued as rs1444200944, COSV52057661; called by muse, mutect2, varscan2
- RB1 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 31/44 reads (70%) | catalogued as rs1131690869, COSV99927216; called by muse, mutect2, varscan2
- RBP4 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65159822; called by muse, mutect2, varscan2
- RYR1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs773794000, COSV62098661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL4 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV53851049; called by muse, mutect2, varscan2
- SLFN11 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV57698167; called by muse, mutect2, varscan2
- SYNE2 | c.9826G>A p.E3276K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV59945012; called by muse, mutect2, varscan2
- TPPP | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144404274; called by muse, mutect2, varscan2
- TRIM3 | c.1631A>G p.N544S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as rs369921459; called by muse, mutect2, varscan2
- TRNAU1AP | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65777650; called by muse, mutect2, varscan2
- VCAN | c.5126C>A p.T1709K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV54101601; called by muse, mutect2, varscan2
- ZFHX3 | c.5870T>G p.V1957G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51713334; called by muse, mutect2, varscan2
- ZFYVE16 | c.253del p.L85Sfs*13 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as COSV62015160; called by mutect2, pindel, varscan2
- ZNF148 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1471213755, COSV62303607; called by muse, mutect2, varscan2
- ZNF423 | c.3080G>T p.G1027V (on ENST00000563137 / NM_001379286.1; = p.G1019V on NM_015069.4) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1478373402, COSV52183042; called by muse, mutect2, varscan2
- SHH | c.504del p.G169Afs*17 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- ZNF668 | c.105_126del p.R36Hfs*14 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- CCDC125 | c.609A>G p.K203= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs1486150406, COSV67287860; called by muse, mutect2, varscan2
- CRYAB | c.291G>C p.V97= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV57051505; called by muse, mutect2, varscan2
- DCUN1D2 | c.171G>A p.R57= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as COSV60260986; called by muse, mutect2, varscan2
- EMILIN2 | c.363T>C p.G121= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV54422359; called by muse, mutect2, varscan2
- HAUS5 | c.579C>T p.T193= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV52547322; called by muse, mutect2, varscan2
- IL31RA | c.1413C>T p.I471= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV51680745; called by muse, mutect2, varscan2
- KCNE4 | c.504C>G p.L168= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs760380181, COSV56054312; called by muse, mutect2, varscan2
- PGAP1 | c.2115G>A p.V705= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs777737461; called by muse, mutect2
- PIH1D2 | c.742C>T p.L248= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV54775139; called by muse, mutect2, varscan2
- PLCG1 | c.1584C>T p.G528= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99719400; called by muse, mutect2
- RPL23 | c.171G>T p.V57= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV55559679; called by muse, mutect2, varscan2
- SHC1 | c.1698C>T p.I566= (on ENST00000368445 / NM_183001.5; = p.I457= on NM_003029.5) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV63534672; called by muse, mutect2, varscan2
- SLIT1 | c.954G>A p.L318= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV56586004; called by muse, mutect2, varscan2
- TSPOAP1 | c.2106C>G p.L702= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1334844245, COSV99273217; called by muse, mutect2
- UBA6 | c.510C>T p.I170= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as COSV100451573, COSV59175638, COSV59180793; called by muse, mutect2, varscan2
- ZBED4 | c.255G>A p.A85= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs567666505, COSV53464017; called by muse, mutect2, varscan2
- ZBTB22 | c.1125C>G p.V375= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV56467959, COSV56473324; called by muse, mutect2, varscan2
- ZFHX4 | c.2688C>T p.I896= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV50649237; called by muse, mutect2, varscan2
